TCGA case TCGA-CJ-4890 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46d34d0c-b8a2-4ebd-b9a0-5485904ecafa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 72.8 years (26,604 days); Year of diagnosis: 2005; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Initial disease status: Progressive Disease; Days to treatment start: 70 days; Days to treatment end: 211 days; Number of cycles: 4; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib + Tipifarnib; Initial disease status: Progressive Disease; Days to treatment start: 263 days; Days to treatment end: 444 days (1.2 years); Number of cycles: 6; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib Malate; Initial disease status: Progressive Disease; Days to treatment start: 480 days (1.3 years); Days to treatment end: 1,483 days (4.1 years); Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib Tosylate; Initial disease status: Progressive Disease; Days to treatment start: 1,483 days (4.1 years); Days to treatment end: 1,636 days (4.5 years); Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Everolimus; Initial disease status: Progressive Disease; Days to treatment start: 1,636 days (4.5 years); Days to treatment end: 1,698 days (4.6 years); Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 73.0 years (26,674 days); Days to diagnosis: 70 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 76.9 years (28,081 days); Days to diagnosis: 1,477 days (4.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,862 days (5.1 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (5 entries)
- Day 70 (post initial treatment): Progression or recurrence: Yes.
- Day 1,477 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 1,477 days (4.0 years).
- Days to follow up: 2,085 days (5.7 years); Disease response: With Tumor.
- Days to follow up: 3,519 days (9.6 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Hemoglobin: Low.
- Platelets: Normal.
- Lactate Dehydrogenase: Elevated.
- Leukocytes: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.6; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-CJ-4890-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-CJ-4890-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-CJ-4890-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4890-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 0.9; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 1.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: SC.
- Drug treatment 2: Pharmaceutical therapy drug name: Nexavar; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: Sutent; Therapy regimen: Progression.
- Drug treatment 6: Pharmaceutical therapy drug name: Afinitor; Therapy regimen: Progression.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; Performance status timing: At Recurrence/Progression Of Disease.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,519 days; disease-specific survival: no event (censored), 3,519 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 70 days.
